Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-7050, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-7050-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Pathologic Findings & History:

Right renal mass.

Specimens Submitted:

- 1: Kidney, left, upper pole tumor, biopsy (fs) (pjm)
- 2: Kidney, left, lower pole angiomyolipoma, excision (ll)
- 3: Lymph nodes, para-aortic, excision (ll)

DIAGNOSIS:

1. Kidney, left, upper pole tumor, biopsy
Tumor Type:
Renal cell carcinoma - Papillary type

Fuhrman Nuclear Grade:
Nuclear grade III/IV

Tumor Size:
Greatest diameter is 2.2 cm.

Local Invasion (for renal cortical types):
Not Identified

Renal Vein Invasion:
Not identified

Surgical Margins:
Free of tumor
(tumor is present within 0.1 cm of inked renal parenchymal margin)

Non-Neoplastic Kidney:
Unremarkable

Adrenal Gland:
Not identified

Lymph Nodes:
Not identified

Staging for renal cell carcinoma/oncocytoma:
pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

2. Kidney, left, lower pole angiomyolipoma, excision (ll):
Fragmented angiomyolipoma.

[page 2 of 3]
3. Lymph nodes, para-aortic, excision (II):

Lymph Nodes:

Not involved

Number of nodes examined:4

Note:

This case was reviewed with the [REDACTED] which concurs with the diagnosis.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result

Special Stain
RECUT

Comment

Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "Left upper pole renal tumor, stitch marks deep margin" and consists of a portion of brown-tan, kidney tissue measuring 3.5 x 2.5 x 1.8 cm, one stitch is identified designating the deep margin. The deep margin is inked in black and the specimen is serially sectioned to reveal a white-tan, ill defined nodular tumor measuring 2.2 x 1.8 x 1.3 cm. Representative sections are submitted for frozen section. The remaining specimen consists of a portion of brown-tan kidney tissue, perviously inked in black and serially sectioned. Serial sections of the remaining specimen reveals a protruding white-tan nodular tumor measuring 2.2 x 1.8 x 1.3 cm and located abutting the deep black margin of the specimen. Representative submitted. Section was given for [REDACTED] protocol.

Summary of sections:

FSC -- frozen section control

T-representative sections of the tumor

R-representative sections uninvolved parenchyma

2). The specimen is received in formalin, labeled "Left renal lower pole angiomylipoma" and consists of a friable fragment of tan soft tissue measuring 1.7 x 0.6 x 0.5 cm. Entirely submitted.

Summary of sections:

U-undesignated

3). The specimen is received in formalin, labeled "Para-aortic lymph nodes" and consists of four pink-tan firm lymph nodes ranging from 0.8 to 1.5 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

BLN-- bisected lymph nodes

Summary of Sections:

Part 1: Kidney, left, upper pole tumor, biopsy (fs) (pjm)

Block

Sect. Site

PCs

[page 3 of 3]
1	FSC	1
2	R	2
4	T	4

Part 2: Kidney, left, lower pole angiomyolipoma, excision (tl)

Block	Sect. Site	PCs
1	U	1

Part 3: Lymph nodes, para-aortic, excision (tl)

Block	Sect. Site	PCs
2	BLN	4
1	LN	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM (COMES WITHIN 0.05 CM OF INKED MARGIN IN REPRESENTATIVE SECTION)
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file bf0b027d-b22d-4230-aafa-abf9d975b1b8 (TCGA-BQ-7050.420B728A-542F-4300-8EEE-7C5F138D3E66.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).